Somatic mutation profile of tumor specimen 0DE3GW from CCDI case PBBNNM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell carcinoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.2 years (72 days).
Specimen 0DE3GW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8cf4fe7-c2bb-46c2-bf72-4d3980559eae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE3GR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d93dbc1-1e65-4190-b5b5-f48d2c4d9366

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGA4 | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF695 | c.927A>T p.P309= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
